Somatic mutation profile of tumor specimen TCGA-WB-A81A-01A (aliquot TCGA-WB-A81A-01A-11D-A35I-08) from TCGA case TCGA-WB-A81A, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, malignant; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 65.6 years (23,966 days).
Specimen TCGA-WB-A81A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2eae5361-f19d-4b9f-b005-87aeeb7746cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WB-A81A-10A (Blood Derived Normal), aliquot TCGA-WB-A81A-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8bedea94-07c5-47c9-9325-0c1aa1317071

The open-access MAF lists 5 somatic variants for this specimen: 1 protein-altering or splice-affecting, 4 silent.
By variant classification: Silent 4, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NID1 | c.2809G>A p.V937M | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs200467845, COSV51614828; called by muse, mutect2, varscan2
- DDX18 | c.1215T>C p.V405= | Silent (SNP) | VAF 6/79 reads (8%) | called by muse, mutect2
- LRRC37B | c.243G>A p.S81= | Silent (SNP) | VAF 47/102 reads (46%) | catalogued as rs769802492, COSV58952487; called by muse, mutect2, varscan2
- NT5M | c.672C>T p.S224= | Silent (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2, varscan2
- PPP3R2 | c.24G>A p.P8= | Silent (SNP) | VAF 40/91 reads (44%) | catalogued as rs367897972; called by muse, mutect2, varscan2
